Somatic mutation profile of tumor specimen TCGA-67-6217-01A (aliquot TCGA-67-6217-01A-11D-1753-08) from TCGA case TCGA-67-6217, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.7 years (26,920 days).
Specimen TCGA-67-6217-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12c2f455-6d68-4a09-9cda-c38dfacc5824.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-6217-10A (Blood Derived Normal), aliquot TCGA-67-6217-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12e50a65-f017-45a8-b176-10ceb6e8d754

The open-access MAF lists 195 somatic variants for this specimen: 154 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 38, Nonsense Mutation 9, Splice Site 5, Frame Shift Del 3, 5'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 15/100 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11163A>T p.Q3721H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71293238; called by muse, mutect2, varscan2
- ADAMTS5 | c.1211C>A p.A404E | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53184176, COSV99536978; called by muse, mutect2, varscan2
- ADARB1 | c.1517-1G>C p.X506_splice (on ENST00000360697 / NM_001346687.2; = p.X466_splice on NM_001112.4) | Splice Site (SNP) | VAF 11/142 reads (8%) | catalogued as COSV62347425; called by muse, mutect2
- AGTR2 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1556673762, COSV64156960; called by muse, mutect2
- AHNAK2 | c.9730C>A p.P3244T | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100315597, COSV60911140, COSV60927542; called by muse, mutect2, varscan2
- AKR1B15 | c.433A>G p.K145E | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV71152699; called by muse, mutect2, varscan2
- ALG10B | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.265); catalogued as rs1263129774, COSV58144616; called by muse, mutect2, varscan2
- ALPK3 | c.4802C>T p.P1601L | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as rs915374458, COSV51938781; called by muse, mutect2, varscan2
- AMOTL1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54418253; called by muse, mutect2, varscan2
- AMY2B | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 100/417 reads (24%) | catalogued as COSV63715714; called by muse, mutect2, varscan2
- AOAH | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV51749186; called by muse, mutect2, varscan2
- ARFGEF2 | c.4166A>T p.E1389V | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV64214615; called by muse, mutect2, varscan2
- ARID2 | c.1912+1G>T p.X638_splice | Splice Site (SNP) | VAF 14/150 reads (9%) | catalogued as COSV57600946, COSV57612814; called by muse, mutect2
- ARSF | c.834C>A p.H278Q | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV63840797; called by muse, mutect2, varscan2
- ARSG | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756314416, COSV71592753; called by muse, mutect2, varscan2
- ATG10 | c.255T>G p.I85M | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV56431275; called by muse, mutect2, varscan2
- ATP1B4 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs753158669, COSV54314565; called by muse, mutect2
- BACH2 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); catalogued as rs148083597; called by muse, mutect2, varscan2
- C2orf80 | c.42G>T p.L14F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100378208; called by muse, mutect2, varscan2
- C2orf80 | c.42-1G>T p.X14_splice | Splice Site (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100378209; called by muse, mutect2, varscan2
- CASP8AP2 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV52749360; called by muse, mutect2, varscan2
- CASS4 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV64388089; called by muse, mutect2, varscan2
- CCDC7 | c.3811C>T p.R1271C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1415188403, COSV56550300; called by muse, mutect2, varscan2
- CCNB1 | c.407C>A p.A136D | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV56510240, COSV99841157; called by muse, mutect2
- CDH12 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.712); catalogued as COSV66440614, COSV66453488; called by muse, mutect2, varscan2
- CDKN2D | c.405G>C p.R135S | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV100224672; called by muse, mutect2
- CFAP58 | c.696G>T p.M232I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV57213419; called by muse, mutect2, varscan2
- CLPSL1 | c.264C>A p.N88K | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV65815139; called by muse, mutect2, varscan2
- CMYA5 | c.6349G>C p.D2117H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.145); catalogued as COSV101483850, COSV71408990; called by muse, mutect2, varscan2
- CNTN2 | c.1883G>A p.W628* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV59352407; called by muse, mutect2, varscan2
- CNTNAP5 | c.2722C>A p.L908M | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV70507723; called by muse, mutect2, varscan2
- CR1 | c.2696C>A p.T899K | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as CM124630, COSV65462257; called by muse, mutect2, varscan2
- CSMD1 | c.9197C>A p.P3066Q (on ENST00000520002; = p.P3065Q on NM_033225.6) | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59371921; called by muse, mutect2, varscan2
- CYP2U1 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60549545; called by muse, mutect2, varscan2
- DNAH7 | c.2289G>T p.L763F | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV56781295; called by muse, mutect2
- ELK4 | c.1081-2A>T p.X361_splice | Splice Site (SNP) | VAF 39/87 reads (45%) | catalogued as COSV56986043; called by muse, mutect2, varscan2
- FAT2 | c.3281C>A p.P1094H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.631); catalogued as COSV55819913, COSV55827723; called by muse, mutect2
- FBN2 | c.8114C>A p.P2705H | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52539840; called by muse, mutect2, varscan2
- FLG | c.11027C>A p.T3676K | Missense Mutation (SNP) | VAF 72/404 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.791); catalogued as COSV100910243; called by muse, mutect2, varscan2
- GALNT6 | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100695243, COSV100695686; called by muse, mutect2, varscan2
- GATAD2B | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV64085688; called by muse, mutect2, varscan2
- GATM | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as rs80338737, CM013263, COSV67541037; called by muse, mutect2, varscan2
- GBP5 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58594100; called by muse, mutect2, varscan2
- GOLGB1 | c.5770G>T p.E1924* | Nonsense Mutation (SNP) | VAF 58/191 reads (30%) | catalogued as COSV61469961; called by muse, mutect2, varscan2
- GRM5 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781196829, COSV59595091; called by muse, mutect2, varscan2
- HLX | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771667084, COSV65045536; called by muse, mutect2, varscan2
- HTATSF1 | c.1037C>G p.A346G | Missense Mutation (SNP) | VAF 84/416 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV54480790; called by muse, mutect2, varscan2
- HTR1E | c.977C>A p.A326D | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.333); catalogued as COSV59510431; called by muse, mutect2, varscan2
- HYOU1 | c.1439A>G p.K480R | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68217134; called by muse, mutect2, varscan2
- IKZF2 | c.1298G>T p.S433I | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.665); catalogued as COSV59583102; called by muse, mutect2
- ITGA8 | c.2114A>G p.N705S | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs1381016791, COSV65234661; called by muse, mutect2, varscan2
- ITGAL | c.2783A>T p.Q928L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV63323849; called by muse, mutect2, varscan2
- KCNH1 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55079180, COSV55098414; called by muse, mutect2, varscan2
- KCTD14 | c.134C>G p.T45S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV62002021; called by muse, mutect2, varscan2
- KIAA1210 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV68179581; called by muse, mutect2, varscan2
- KIF20B | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773209778, COSV53314275; called by muse, mutect2
- KL | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV66309809; called by muse, mutect2, varscan2
- KLHL24 | c.1732A>G p.M578V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs763486521, COSV54428318; called by muse, mutect2, varscan2
- KMT2C | c.9065C>T p.T3022I | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.216); catalogued as rs141345566; called by muse, mutect2, varscan2
- KRT1 | c.807-2A>G p.X269_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as COSV52868899; called by muse, mutect2, varscan2
- KRT222 | c.194T>A p.L65Q | Missense Mutation (SNP) | VAF 105/293 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV67498964; called by muse, mutect2, varscan2
- KRTAP10-6 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100551198, COSV100553559; called by muse, mutect2, varscan2
- KRTAP24-1 | c.452G>C p.C151S | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.063); catalogued as COSV100447261; called by muse, mutect2, varscan2
- LAYN | c.648A>C p.E216D (on ENST00000375615 / NM_001258390.1; = p.E208D on NM_178834.5) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV65105417; called by muse, mutect2, varscan2
- LRIG3 | c.1983C>A p.F661L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV57868981; called by muse, mutect2, varscan2
- LUM | c.378C>G p.N126K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99898820; called by muse, mutect2, varscan2
- MAGEC1 | c.1469C>A p.T490N | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as COSV53573455, COSV53579791; called by muse, mutect2, varscan2
- MAGEH1 | c.473A>C p.E158A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as COSV61679145; called by muse, mutect2
- MAGEH1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.076); catalogued as COSV61679152; called by muse, mutect2, varscan2
- MDGA1 | c.214T>C p.W72R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99775963; called by muse, mutect2, varscan2
- MDH1B | c.977G>T p.R326M | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV65591262; called by muse, mutect2, varscan2
- MECOM | c.274A>G p.K92E (on ENST00000468789 / NM_001105078.4; = p.K280E on NM_004991.4) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.446); catalogued as COSV52972542; called by muse, mutect2
- MRPS7 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748731229, COSV55454214; called by muse, mutect2, varscan2
- MTM1 | c.1277A>T p.D426V | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV60337197; called by muse, mutect2
- MUC17 | c.7372T>A p.L2458I | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV60300556; called by muse, mutect2, varscan2
- MYH2 | c.4294G>C p.E1432Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55435723, COSV55437149; called by muse, mutect2, varscan2
- NAV3 | c.6050T>A p.L2017H (on ENST00000397909 / NM_001024383.2; = p.L1995H on NM_014903.6) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57106632; called by muse, mutect2, varscan2
- NCKAP5 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV58469578; called by muse, mutect2
- NELL1 | c.2379C>A p.C793* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | catalogued as COSV54314250; called by muse, mutect2, varscan2
- NEURL4 | c.3863A>G p.Q1288R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV59752858; called by muse, mutect2
- NOTCH4 | c.1790C>A p.P597Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764974160, COSV100900241; called by muse, mutect2, varscan2
- NOTCH4 | c.1789C>A p.P597T | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100900243; called by muse, mutect2, varscan2
- NUP210L | c.3948G>T p.R1316S | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV55155832; called by muse, mutect2
- OPRK1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV55571174; called by muse, mutect2, varscan2
- OR11H12 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs879092737; called by muse, mutect2, varscan2
- OR2M3 | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 78/444 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV71759208, COSV71759244; called by muse, varscan2
- OR2T10 | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs761526786, COSV57898110; called by muse, mutect2, varscan2
- OR51A7 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs753540022, COSV63788198, COSV63788875; called by muse, mutect2, varscan2
- OR5A1 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100118435, COSV57377990; called by muse, mutect2, varscan2
- OR5D13 | c.767C>A p.T256N | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs753838527, COSV62334387; called by muse, mutect2, varscan2
- OR5M8 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1408563324, COSV59117967; called by muse, mutect2, varscan2
- OR5T3 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 98/307 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57382233; called by muse, mutect2, varscan2
- OR8K3 | c.830A>T p.Y277F | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57132321, COSV57132786; called by muse, mutect2, varscan2
- OSBPL1A | c.676G>C p.V226L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV60202696; called by muse, mutect2, varscan2
- PAK3 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 84/163 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV99456072; called by muse, mutect2, varscan2
- PCDHB10 | c.952A>T p.N318Y | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.16); catalogued as COSV53382898; called by muse, mutect2
- PDK1 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV99961015; called by muse, mutect2, varscan2
- PLEKHG2 | c.3256G>C p.D1086H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.599); catalogued as rs1450800476, COSV52688894; called by muse, mutect2, varscan2
- PLP2 | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.105); catalogued as COSV66240548; called by muse, mutect2, varscan2
- PNLIPRP2 | c.72A>T p.Q24H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV53946208; called by muse, mutect2, varscan2
- POU3F4 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV64540727; called by muse, mutect2, varscan2
- PROKR2 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV54088820; called by muse, mutect2, varscan2
- PROS1 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV67776833; called by muse, mutect2
- PTPDC1 | c.881A>G p.K294R (on ENST00000375360 / NM_177995.3; = p.K346R on NM_152422.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as rs775317144, COSV56625844; called by muse, mutect2, varscan2
- RASAL2 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62721454; called by muse, mutect2
- RNF19B | c.1906C>A p.P636T | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV52389656; called by muse, mutect2, varscan2
- RPP40 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100123829; called by muse, mutect2, varscan2
- RSRC1 | c.887A>G p.D296G | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV55837205; called by muse, mutect2, varscan2
- S100A13 | c.206C>G p.S69W | Missense Mutation (SNP) | VAF 21/509 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1283885643, COSV100275071, COSV59884686; called by muse, mutect2
- SFMBT2 | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs566901683, COSV62815311; called by muse, mutect2, varscan2
- SIGLEC10 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100218336; called by muse, mutect2
- SLC12A5 | c.2717G>A p.R906H (on ENST00000454036 / NM_001134771.2; = p.R883H on NM_020708.5) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV99714960; called by muse, mutect2
- SLC44A5 | c.67T>A p.Y23N | Missense Mutation (SNP) | VAF 180/533 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV63772998; called by muse, mutect2, varscan2
- SLC6A13 | c.1769C>A p.T590N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58259826; called by muse, mutect2, varscan2
- SLITRK2 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1313895330, COSV59426603; called by muse, mutect2, varscan2
- SLITRK6 | c.1019C>A p.P340Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV101233150; called by muse, mutect2, varscan2
- SLITRK6 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.081); catalogued as COSV101233153; called by muse, mutect2, varscan2
- SMO | c.1924G>T p.V642L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV50839854; called by muse, mutect2, varscan2
- SOHLH1 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV53683606; called by muse, mutect2
- SPATA31D1 | c.3080G>T p.R1027I | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as COSV61200223; called by muse, mutect2, varscan2
- SPATA31E1 | c.2870G>T p.G957V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs181272197, COSV57794535; called by muse, mutect2, varscan2
- SRSF10 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs987729296; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 31/161 reads (19%) | PolyPhen possibly damaging (0.664); catalogued as COSV60346119; called by muse, mutect2, varscan2
- ST8SIA3 | c.669G>C p.L223F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | PolyPhen benign (0.158); catalogued as COSV60655095; called by muse, mutect2, varscan2
- STOML3 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65510166; called by muse, mutect2, varscan2
- TACR3 | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV59202940; called by muse, mutect2, varscan2
- TBX5 | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 25/166 reads (15%) | catalogued as COSV59864561; called by muse, mutect2, varscan2
- TENM3 | c.4316C>T p.S1439F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as COSV69308719; called by muse, mutect2, varscan2
- TEX37 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV57556641; called by muse, mutect2, varscan2
- TEX37 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57555651; called by muse, mutect2, varscan2
- TMEM168 | c.1110G>T p.L370F | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV57182207; called by muse, mutect2, varscan2
- TRPS1 | c.652G>T p.E218* (on ENST00000220888 / NM_001330599.2; = p.E231* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/134 reads (34%) | catalogued as COSV55257872; called by muse, mutect2, varscan2
- TSHZ2 | c.1357T>A p.C453S | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61590927; called by muse, mutect2, varscan2
- UGT2B7 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59445160; called by muse, mutect2, varscan2
- USH2A | c.7192C>T p.L2398F | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV56422483; called by muse, mutect2, varscan2
- VPS13C | c.5820T>G p.F1940L (on ENST00000644861 / NM_020821.3; = p.F1897L on NM_017684.5) | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV51420386; called by muse, mutect2
- WLS | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557481488, COSV99258137; called by muse, mutect2, varscan2
- ZBED9 | c.1633C>A p.H545N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV71729727; called by muse, mutect2
- ZNF169 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100566102; called by muse, mutect2, varscan2
- ZNF462 | c.6953A>T p.H2318L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52949065; called by muse, mutect2, varscan2
- ZNF516 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71587546, COSV71587653; called by muse, mutect2, varscan2
- ZNF551 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142211450, COSV56594680; called by muse, mutect2, varscan2
- ZNF638 | c.2709A>C p.E903D | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.142); catalogued as COSV52495141; called by muse, mutect2
- AHNAK2 | c.9235C>A p.P3079T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ATG2B | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- FCGBP | c.156C>A p.Y52* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- GATAD2A | c.1369del p.R457Gfs*2 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- MSMB | c.265A>T p.K89* | Nonsense Mutation (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- PCDH9 | c.778C>A p.H260N | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2
- RSBN1 | c.2025_2043del p.I675Mfs*15 | Frame Shift Del (DEL) | VAF 34/172 reads (20%) | called by mutect2, pindel
- STXBP5L | c.2106del p.I702Mfs*17 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- TBC1D3B | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.823); called by mutect2, varscan2
- TNXB | c.12019C>A p.R4007S (on ENST00000647633; = p.R3760S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ADAMTSL1 | c.531C>A p.V177= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV52822855; called by muse, mutect2, varscan2
- ADGRB2 | c.3636G>A p.V1212= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV57077941; called by muse, mutect2
- AP3D1 | c.2442G>A p.E814= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV61432039; called by muse, mutect2, varscan2
- AP3D1 | c.1470G>A p.G490= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV61432121; called by muse, mutect2, varscan2
- ATP8B4 | c.1023C>T p.S341= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as COSV52722638; called by muse, mutect2
- BANK1 | c.1173C>T p.H391= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV59848647; called by muse, mutect2
- CHD5 | c.3609C>T p.D1203= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs542019061, COSV52413931; called by muse, mutect2, varscan2
- CPN1 | c.1083C>A p.V361= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV64942713; called by muse, mutect2, varscan2
- CSNK1G1 | c.420G>T p.T140= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100273785; called by muse, mutect2
- DUOX1 | c.3351C>T p.L1117= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV58485671, COSV58487098; called by muse, mutect2, varscan2
- EPHA7 | c.1276C>A p.R426= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV65180881, COSV65181105, COSV65189853; called by muse, mutect2, varscan2
- FAM50A | c.981C>T p.Y327= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs782547697, COSV50132201; called by muse, mutect2
- FAP | c.1011G>A p.E337= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV99501450; called by muse, mutect2, varscan2
- FZD2 | c.274C>T p.L92= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs1204453011, COSV100190171; called by muse, mutect2
- HSPA1L | c.198G>A p.Q66= | Silent (SNP) | VAF 90/156 reads (58%) | catalogued as COSV65149390; called by muse, mutect2, varscan2
- HSPH1 | c.1551G>T p.L517= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV60713495; called by muse, mutect2, varscan2
- MAGEC2 | c.771G>C p.G257= | Silent (SNP) | VAF 67/260 reads (26%) | catalogued as COSV55997908, COSV56001116; called by muse, mutect2, varscan2
- MUC16 | c.23478T>G p.A7826= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs765190962, COSV67487937; called by muse, mutect2, varscan2
- OPRK1 | c.882C>A p.I294= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV55570408; called by muse, mutect2, varscan2
- OR52H1 | c.918A>T p.I306= (on ENST00000322653; = p.I312= on NM_001005289.1) | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100497221; called by muse, mutect2, varscan2
- PCDH9 | c.777G>C p.V259= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100117131, COSV100118262; called by muse, mutect2
- PCDHA8 | c.1323G>A p.L441= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV65339394, COSV65339829; called by muse, mutect2
- PCDHB6 | c.153G>A p.L51= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV50719990; called by muse, mutect2, varscan2
- PLEC | c.13383C>T p.P4461= (on ENST00000322810 / NM_201380.4; = p.P4351= on NM_000445.5) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV59604709; called by muse, mutect2, varscan2
- PRELID3B | c.39G>T p.P13= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100582049; called by muse, mutect2, varscan2
- PRKD1 | c.1617C>T p.A539= | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as rs1213383041, COSV59582743; called by muse, mutect2
- RAB3B | c.9A>G p.S3= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV100784857; called by muse, mutect2, varscan2
- SCN10A | c.2364G>C p.G788= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV71862521; called by muse, mutect2
- SDK1 | c.1044C>T p.T348= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV67385433; called by muse, mutect2
- SYNE1 | c.1290C>A p.T430= (on ENST00000367255 / NM_182961.4; = p.T437= on NM_033071.3) | Silent (SNP) | VAF 80/180 reads (44%) | catalogued as COSV54994967, COSV55077460; called by muse, mutect2, varscan2
- TMEM204 | c.453C>A p.I151= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV54152411, COSV99559551; called by muse, mutect2, varscan2
- TNXB | c.12018C>A p.P4006= (on ENST00000647633; = p.P3759= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- TPSG1 | c.411C>A p.L137= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV52357554; called by muse, mutect2, varscan2
- TRPV6 | c.174G>A p.K58= | Silent (SNP) | VAF 17/163 reads (10%) | catalogued as COSV63893249; called by muse, mutect2, varscan2
- TSPOAP1 | c.2280G>T p.V760= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV52116033; called by muse, mutect2, varscan2
- UTP14A | c.2157C>G p.P719= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV64087404, COSV64087769; called by muse, mutect2, varscan2
- ZC3H3 | c.1848C>T p.L616= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV52794163, COSV99367667; called by muse, mutect2, varscan2
- ZNF217 | c.1743T>C p.S581= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs747606027, COSV56601245; called by muse, mutect2, varscan2
- PCDH18 | c.-2C>A | 5'UTR (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100786880; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827779 A>G | 3'Flank (SNP) | VAF 31/117 reads (26%) | catalogued as COSV59428096; called by muse, mutect2, varscan2
- TMEM105 | n.709G>T | RNA (SNP) | VAF 39/111 reads (35%) | catalogued as COSV100129554; called by muse, mutect2, varscan2
